CPTAC case C3L-00965 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/217bbeb4-6b93-47d9-808f-14fd17e9b3b4

Demographics
Sex at birth: male; Race: white; Year of birth: 1953; Vital status: Alive; Country of birth: Russia.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 63.8 years (23,305 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,857 days (5.1 years); Progression or recurrence: no; Days to last follow up: 1,857 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 18; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 451 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 846 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,148 days (3.1 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,470 days (4.0 years); Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 0.
- Days to follow up: 1,470 days (4.0 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 0.
- Days to follow up: 1,857 days (5.1 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 61 kg; Height: 161 cm; BMI: 23.53.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 42; Cigarettes per day: 20; Tobacco smoking onset year: 1974; Tobacco smoking quit year: 2016; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 42.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00965-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 230 mg.
- Sample C3L-00965-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 210 mg.
- Sample C3L-00965-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 31 days; Initial weight: 240 mg; Time between clamping and freezing: 26 minutes; Time between excision and freezing: 1 minute; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00965-23: Section location: Right Upper Lobe; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3L-00965-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 270 mg.
- Sample C3L-00965-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 160 mg.
- Sample C3L-00965-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 590 mg.
- Sample C3L-00965-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 31 days; Method of sample procurement: Blood Draw.
- Sample C3L-00965-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
